Gene-level copy-number profile of tumor specimen TCGA-AJ-A3BF-01A from TCGA case TCGA-AJ-A3BF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 65.5 years (23,906 days).
Specimen TCGA-AJ-A3BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.2372ec32-42d1-471b-8598-46b6ea83402e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3BF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e326240e-98ef-4f9a-9cbf-7059d6e2b655

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 12,695; copy number 2: 41,244; copy number 3: 3,663; copy number 4: 1,683; copy number 5: 273; copy number 6: 138; copy number 15: 16; copy number 17: 14; copy number 21: 34; copy number 32: 11; copy number 37: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3BF-01A-11D-A20R-01): tumor purity 0.8, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:129,476,946–129,753,042, 11 genes: LINC00963, AL353803.4, AL391056.2, AL391056.1, NTMT1, C9orf50, ASB6, AL590369.1, PRRX2, PRRX2-AS1, PTGES.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 502 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,596,215–22,157,401, 23 genes, copy number 5 (within-gene range 2–5): RAP1GAP, USP48, AL590103.1, LDLRAD2, HSPG2, AL590556.1, AL590556.2, CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1, WNT4, AL445253.1.
- chr1:150,487,364–151,831,845, 86 genes, copy number 5 (broad region; genes not listed).
- chr1:205,566,716–206,464,443, 29 genes, copy number 6 (within-gene range 2–6): RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1, AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1.
- chr6:43,722,786–44,378,957, 25 genes, copy number 5 (within-gene range 2–5): AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2.
- chr7:23,100,214–23,832,513, 26 genes, copy number 6: KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7.
- chr7:32,868,172–33,109,404, 9 genes, copy number 5: KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9.
- chr7:33,128,988–33,277,091, 3 genes, copy number 5: AC074338.1, RNA5SP229, AC007312.1.
- chr7:43,758,680–44,334,577, 31 genes, copy number 6 (within-gene range 2–6): BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B.
- chr7:74,289,407–74,890,610, 11 genes, copy number 5 (within-gene range 2–5): CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2.
- chr7:149,126,416–149,297,312, 7 genes, copy number 5 (within-gene range 2–5): ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2.
- chr8:127,072,694–127,227,541, 1 gene, copy number 37 (within-gene range 2–37): CASC19.
- chr8:127,253,213–128,564,679, 23 genes, copy number 37: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr10:28,050,993–28,340,942, 5 genes, copy number 15 (within-gene range 2–15): MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1.
- chr10:33,684,755–34,875,422, 11 genes, copy number 15: AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1.
- chr10:59,736,692–59,960,913, 3 genes, copy number 5: MRLN, CCDC6, LINC01553.
- chr10:60,050,668–60,140,877, 3 genes, copy number 5: AL592430.1, Y_RNA, AL592430.2.
- chr12:11,166,090–12,562,863, 34 genes, copy number 21: AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1.
- chr12:25,195,216–25,648,579, 11 genes, copy number 32 (within-gene range 1–32): ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1.
- chr12:46,183,063–47,079,959, 14 genes, copy number 17 (within-gene range 1–17): SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2.
- chr14:105,009,573–105,181,323, 11 genes, copy number 5: CDCA4, GPR132, LINC02298, AL512356.4, AL512356.3, AL512356.2, AL512356.5, JAG2, MIR6765, AL512356.1, NUDT14.
- chr15:40,528,683–40,807,478, 14 genes, copy number 5 (within-gene range 2–5): CCDC32, RNU6-516P, RPUSD2, Metazoa_SRP, KNL1, RN7SL376P, AC022405.1, RAD51-AS1, RAD51, RMDN3, SUMO2P15, GCHFR, DNAJC17, C15orf62.
- chr17:81,843,161–81,860,624, 1 gene, copy number 5 (within-gene range 2–5): P4HB.
- chr17:81,862,778–82,698,698, 69 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:58,183,029–58,605,223, 52 genes, copy number 6 (within-gene range 4–6): ZNF274, RPS15AP36, AC020915.3, ZNF544, AC020915.4, AC020915.2, AC020915.1, ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.

Autosomal genes at a single copy (total copy number 1): 12,695. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
